Somatic mutation profile of tumor specimen TCGA-FG-7641-01B (aliquot TCGA-FG-7641-01B-11D-2253-08) from TCGA case TCGA-FG-7641, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.1 years (11,357 days).
Specimen TCGA-FG-7641-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d68c4056-6a59-4037-94db-4ec43794121b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-7641-10A (Blood Derived Normal), aliquot TCGA-FG-7641-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c14e5ce-bf93-4108-bccf-08b725f43105

The open-access MAF lists 26 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 22, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50547144, COSV50549541; called by muse, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/142 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CCDC113 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV54685335; called by muse, mutect2, varscan2
- CIC | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50550803, COSV50563193; called by muse, varscan2
- CIC | c.4420G>C p.V1474L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV50550888, COSV50577637; called by muse, mutect2
- DNAH5 | c.10085T>C p.F3362S | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54210291; called by muse, mutect2, varscan2
- EPHA4 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV56028530; called by muse, mutect2, varscan2
- FRAS1 | c.9316G>A p.G3106S | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1331714407, COSV53595990; called by muse, mutect2
- GRIN2A | c.1468A>T p.N490Y | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58024460; called by muse, mutect2
- HTRA3 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as rs369645804, COSV56470026; called by muse, mutect2, varscan2
- KCNB2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049052; called by muse, mutect2, varscan2
- MCPH1 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs777703312, COSV60911163; called by muse, mutect2
- PARP12 | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54932833; called by muse, mutect2, varscan2
- PCDHB5 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50648085; called by muse, mutect2, varscan2
- PTPN11 | c.155C>G p.T52S | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as CM122798, COSV61006484, COSV61013714; called by muse, mutect2, varscan2
- QTRT1 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51550404; called by muse, mutect2, varscan2
- RBM26 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.255); catalogued as COSV57392290; called by muse, mutect2
- REV1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV51482697; called by muse, mutect2
- RHAG | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV57703441; called by muse, mutect2, varscan2
- TNFAIP6 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs777710715, COSV54640199; called by muse, mutect2
- UHRF1BP1L | c.207G>A p.R69= | Splice Region (SNP) | VAF 29/100 reads (29%) | catalogued as COSV54435308; called by muse, mutect2, varscan2
- VCAN | c.9592C>T p.R3198C | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773096484, COSV54099409, COSV54105278; called by muse, mutect2, varscan2
- ZBTB45 | c.117T>G p.I39M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63523406; called by mutect2, varscan2
- DCANP1 | c.9C>T p.Y3= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs113239442; called by mutect2, varscan2
- HYAL3 | c.60C>T p.G20= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV56496994; called by muse, mutect2
- NUP88 | c.792A>T p.A264= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV56703316; called by muse, mutect2, varscan2
